MMRF case MMRF_2015 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/10a453ce-b0c4-4045-86c1-24d8fb08ac71

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 533 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.0 years (23,749 days); ISS stage: II; Days to last known disease status: 533 days (1.5 years); Days to last follow up: 533 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 23 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days; Days to treatment end: 138 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 258 days; Days to treatment end: 258 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 533.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 8 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.29 mg/dL; Immunoglobulin G 3.14 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 32.4 g/L; Beta 2 Microglobulin 1.96 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 30 g/L; Total Protein 10.8 g/dL; Glucose 7.21 mmol/L.
- Day 112 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.34 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 182 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.21 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.78 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 476 (ECOG 0): Hemoglobin 7.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 6.93 mmol/L.

Other clinical attributes
- Day 8: Weight: 92 kg; Height: 187 cm.

Biospecimens (3 samples)
- Sample MMRF_2015_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 8 days.
- Sample MMRF_2015_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 8 days.
- Sample MMRF_2015_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 476 days (1.3 years).
